Somatic mutation profile of tumor specimen TCGA-BS-A0U7-01A (aliquot TCGA-BS-A0U7-01A-21D-A10B-09) from TCGA case TCGA-BS-A0U7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 63.4 years (23,166 days).
Specimen TCGA-BS-A0U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 383e4efc-c165-4bca-81ab-3e8cbf712977.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0U7-10A (Blood Derived Normal), aliquot TCGA-BS-A0U7-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c74174f-a09f-4e36-b9d4-e6efe39cd3dc

The open-access MAF lists 227 somatic variants for this specimen: 163 protein-altering or splice-affecting, 61 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 61, Nonsense Mutation 14, Frame Shift Del 11, Frame Shift Ins 10, Splice Site 4, RNA 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs80356703, CM950270, COSV58369252; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 50/223 reads (22%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 85/277 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- PIK3R2 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs886041591, CM1511569, COSV55849784; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 107/222 reads (48%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TBC1D20 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 43/137 reads (31%) | catalogued as rs587777157, CM1312371, COSV62613291; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD4 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748028569, COSV53529632, COSV53530431; called by muse, mutect2, varscan2
- ACP7 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV58700538; called by muse, mutect2, varscan2
- ACSF2 | c.1797+1G>A p.X599_splice | Splice Site (SNP) | VAF 6/130 reads (5%) | catalogued as COSV51956879; called by muse, mutect2
- ADA | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as CM114610, COSV63069135; called by muse, mutect2, varscan2
- AEBP1 | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); catalogued as COSV56260396; called by muse, mutect2, varscan2
- AMOT | c.1601G>T p.R534I (on ENST00000371959 / NM_001113490.1; = p.R125I on NM_133265.3) | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV59067114; called by muse, mutect2
- ANK3 | c.3985C>T p.R1329* (on ENST00000280772 / NM_001320874.2; = p.R463* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 22/129 reads (17%) | catalogued as COSV55051656; called by muse, mutect2, varscan2
- ANKIB1 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); catalogued as rs760743621, COSV56061265; called by muse, mutect2, varscan2
- ANKRD26 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766853628, COSV65777422; called by muse, mutect2, varscan2
- ANXA10 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs181214351, COSV63740033; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 22/40 reads (55%) | catalogued as rs758608743; called by mutect2, varscan2
- ARID4B | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 33/339 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.372); catalogued as COSV51609314; called by muse, mutect2
- ATXN2L | c.2804C>A p.P935H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV57377284; called by muse, mutect2, varscan2
- BAP1 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV56239140; called by muse, mutect2, varscan2
- BICRAL | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV58407903; called by muse, mutect2
- BRD3 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421524261, COSV57701718, COSV57704744; called by muse, mutect2, varscan2
- BRINP1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs760997991, COSV56310156; called by muse, mutect2, varscan2
- BTRC | c.740G>T p.G247V (on ENST00000370187 / NM_033637.4; = p.G211V on NM_003939.5) | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as COSV64562844; called by muse, mutect2, varscan2
- C1orf43 | c.278G>T p.G93V (on ENST00000368521 / NM_001297718.2; = p.G59V on NM_015449.4) | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV62966715; called by muse, mutect2
- C5orf24 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755244010, COSV57542764; called by muse, mutect2, varscan2
- CA8 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as rs772437360, COSV58771201; called by muse, mutect2, varscan2
- CAMSAP1 | c.4574C>T p.A1525V | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1404722706, COSV56721344; called by muse, mutect2
- CD40 | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64848187; called by muse, mutect2
- CDK11B | c.1471A>G p.K491E | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV58340467; called by muse, mutect2, varscan2
- CHRD | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | catalogued as COSV52609928; called by muse, mutect2
- CHRM4 | c.1366T>C p.C456R | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58993614; called by muse, mutect2, varscan2
- COG3 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as rs1183473937, COSV63074663; called by muse, mutect2
- COL6A3 | c.1947C>A p.N649K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); catalogued as rs778681864, COSV55081607, COSV55103939; called by muse, mutect2, varscan2
- CPED1 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as rs773348723, COSV59998650, COSV60010420; called by muse, mutect2, varscan2
- CS | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60834496; called by muse, mutect2, varscan2
- CWH43 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56942781; called by muse, mutect2, varscan2
- CYP2A6 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs376782364; called by muse, varscan2
- DDHD2 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 105/333 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV68158550; called by muse, mutect2, varscan2
- DDX42 | c.86C>G p.P29R | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV63791060; called by muse, mutect2, varscan2
- DDX53 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60069795; called by muse, mutect2, varscan2
- DERA | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as rs754049202, COSV70775185; called by muse, mutect2, varscan2
- DHTKD1 | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145427732; called by muse, mutect2, varscan2
- DHX38 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs780828640, COSV51700215; called by muse, mutect2, varscan2
- DMD | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55894300; called by muse, mutect2, varscan2
- DRD5 | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58579862; called by muse, mutect2, varscan2
- DSCAM | c.4701C>A p.N1567K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV68033592; called by muse, mutect2, varscan2
- EPHA10 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57624164; called by muse, mutect2, varscan2
- FAM234B | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52196763; called by muse, mutect2, varscan2
- FBN2 | c.8138C>T p.T2713M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as rs754101758, COSV52537845; called by muse, mutect2, varscan2
- FGL1 | c.417C>A p.D139E | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.221); catalogued as COSV67713307; called by muse, mutect2
- FLG | c.11549C>T p.S3850L | Missense Mutation (SNP) | VAF 244/441 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV100912181, COSV64246185; called by muse, mutect2, varscan2
- FREM1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757140817, COSV63087238; called by muse, mutect2
- G3BP2 | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 28/441 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV62977352; called by muse, mutect2
- GIPC2 | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV66129194; called by muse, mutect2, varscan2
- GOLT1A | c.221del p.G74Vfs*64 | Frame Shift Del (DEL) | VAF 37/210 reads (18%) | catalogued as rs765260894; called by mutect2, pindel, varscan2
- GPC5 | c.1403T>A p.L468* | Nonsense Mutation (SNP) | VAF 12/238 reads (5%) | catalogued as COSV65621609; called by muse, mutect2
- GPC5 | c.1404G>T p.L468F | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV65621614; called by muse, mutect2
- GPRC6A | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs754816180, COSV59954746, COSV59955335; called by muse, mutect2, varscan2
- GREB1 | c.5717G>A p.R1906Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343965206, COSV52194336; called by muse, mutect2, varscan2
- GRIA3 | c.1906G>T p.V636F | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52076424; called by muse, mutect2, varscan2
- GRK3 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs767670960, COSV60799522; called by muse, mutect2
- HCN3 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs776848448, COSV64234941; called by muse, mutect2, varscan2
- HERC6 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756622815, COSV52031851, COSV99986792; called by muse, mutect2, varscan2
- HGF | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 103/424 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV55954994; called by muse, mutect2, varscan2
- IGFALS | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs888881437, COSV51905271; called by muse, mutect2
- INAVA | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.867); catalogued as COSV66257324; called by muse, mutect2, varscan2
- KCNG1 | c.1261A>C p.T421P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV65370208; called by muse, mutect2
- KIF19 | c.2240T>C p.L747P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs778492991, COSV63430347; called by muse, mutect2, varscan2
- KIF21B | c.2155C>T p.R719W | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV59764114; called by muse, mutect2, varscan2
- KLF11 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs541774526, COSV59940424; called by muse, mutect2, varscan2
- KLHL6 | c.1564+2T>C p.X522_splice | Splice Site (SNP) | VAF 11/104 reads (11%) | catalogued as COSV58068697; called by muse, mutect2, varscan2
- KRT35 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.537); catalogued as rs199804026, COSV55844318; called by muse, mutect2, varscan2
- LBP | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV54142803; called by muse, mutect2
- LCLAT1 | c.1050A>G p.I350M | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV58377126; called by muse, mutect2
- LDHB | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV63365454; called by muse, mutect2
- LRBA | c.1490T>C p.I497T | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV63962510; called by muse, mutect2, varscan2
- LRRC49 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs377618599; called by muse, mutect2
- MCM4 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs768674866, COSV100031817, COSV50630362; called by muse, mutect2, varscan2
- MCOLN2 | c.1481T>A p.F494Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280423285, COSV52293943; called by muse, mutect2, varscan2
- METTL21A | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV55881951; called by muse, mutect2
- MMS22L | c.2902C>T p.R968W | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs202094067, COSV51520410; called by muse, mutect2, varscan2
- MUC6 | c.7111C>T p.R2371C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1186646568, COSV59963310, COSV59963815; called by muse, mutect2, varscan2
- NCBP2 | c.17T>A p.L6Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58318190; called by mutect2, varscan2
- NCKAP5 | c.3986C>T p.A1329V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV58467335; called by muse, mutect2, varscan2
- NDOR1 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV61289577; called by muse, mutect2, varscan2
- NFASC | c.1378C>A p.P460T (on ENST00000339876 / NM_001378329.1; = p.P471T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58376067; called by muse, mutect2, varscan2
- NMB | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV64685738; called by muse, mutect2, varscan2
- NUP50 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV61661454; called by muse, mutect2, varscan2
- OR5T2 | c.989G>C p.S330T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV57590574; called by muse, mutect2
- PAGE1 | c.249G>T p.R83S | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV65998653; called by muse, mutect2, varscan2
- PDS5B | c.1180A>T p.R394* | Nonsense Mutation (SNP) | VAF 44/181 reads (24%) | catalogued as rs750827034, COSV59724936; called by muse, mutect2, varscan2
- PEG10 | c.805G>A p.D269N (on ENST00000482108 / NM_001040152.2; = p.D303N on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV101509920, COSV71788607; called by muse, mutect2, varscan2
- PITPNM1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs772422561, COSV62709493; called by muse, mutect2, varscan2
- PLXNA3 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.143); catalogued as rs781842825, COSV63755175; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.316A>G p.R106G | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV57967782; called by muse, mutect2
- PRDM9 | c.1030T>C p.C344R | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV57011495; called by muse, mutect2, varscan2
- PRKD1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1174219763, COSV59579267; called by muse, mutect2, varscan2
- PTK2B | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV57763727; called by muse, mutect2, varscan2
- PTOV1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55589841; called by muse, mutect2, varscan2
- RAB13 | c.264C>A p.Y88* | Nonsense Mutation (SNP) | VAF 36/222 reads (16%) | catalogued as COSV100885203, COSV63945582; called by muse, mutect2, varscan2
- RASAL2 | c.1822G>T p.V608F | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV62720861; called by muse, mutect2, varscan2
- RECQL4 | c.518A>G p.Q173R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as COSV52881821; called by muse, mutect2, varscan2
- RTCA | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs751622009, COSV53121987; called by muse, mutect2, varscan2
- RXFP1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530687587, COSV100313965, COSV57046034; called by muse, mutect2, varscan2
- RYR2 | c.1912C>A p.P638T | Missense Mutation (SNP) | VAF 92/175 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63706684; called by muse, mutect2, varscan2
- RYR2 | c.1913C>A p.P638Q | Missense Mutation (SNP) | VAF 93/175 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63706690; called by muse, mutect2, varscan2
- SEPSECS | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57207131; called by muse, mutect2, varscan2
- SEZ6 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.564); catalogued as COSV57983945; called by muse, mutect2, varscan2
- SH3BP5 | c.237A>C p.E79D | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as COSV53746034; called by muse, mutect2, varscan2
- SH3GL3 | c.957T>A p.D319E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61060479; called by muse, mutect2, varscan2
- SIRPG | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 135/466 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53809675; called by muse, mutect2, varscan2
- SLC13A2 | c.1269del p.L423Ffs*26 | Frame Shift Del (DEL) | VAF 38/139 reads (27%) | catalogued as COSV58997886; called by mutect2, pindel, varscan2
- SLC18A2 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53692831; called by muse, mutect2, varscan2
- SLC18A2 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 22/524 reads (4%) | catalogued as COSV53692840; called by muse, mutect2
- SLC1A6 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs180857252, COSV55669026; called by muse, mutect2, varscan2
- SLC2A14 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61588144; called by muse, mutect2, varscan2
- SLC4A2 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs772792069, COSV59658019; called by muse, mutect2, varscan2
- SLC6A20 | c.749_751del p.F250del | In Frame Del (DEL) | VAF 38/141 reads (27%) | catalogued as rs776438424; called by pindel, varscan2
- SLC7A3 | c.1774del p.E592Rfs*16 | Frame Shift Del (DEL) | VAF 81/309 reads (26%) | catalogued as COSV53228942; called by mutect2, pindel, varscan2
- SMPD2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534167199, COSV57806697; called by muse, mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs750890082; called by mutect2, varscan2
- SYMPK | c.1588A>G p.T530A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55614856; called by muse, mutect2, varscan2
- SYNE2 | c.12281C>T p.A4094V | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV59965208; called by muse, mutect2
- SZT2 | c.2662G>A p.D888N | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65173259; called by muse, mutect2, varscan2
- TAF4 | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV53342099; called by muse, mutect2
- TAP1 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as rs778774698, COSV62754343; called by muse, mutect2, varscan2
- TAS2R43 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV67861456; called by muse, mutect2
- TJP1 | c.2395T>C p.W799R | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62045284; called by muse, mutect2, varscan2
- TLR5 | c.742A>G p.N248D | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV60559770; called by muse, mutect2, varscan2
- TNFSF12 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1191670290, COSV53432111, COSV53433744; called by muse, mutect2, varscan2
- TRHDE | c.1556A>T p.D519V | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV53860622; called by muse, mutect2, varscan2
- TRIM11 | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV52856639; called by muse, mutect2, varscan2
- TRIP4 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs375028289; called by muse, mutect2, varscan2
- TRPM3 | c.4198C>T p.P1400S (on ENST00000357533 / NM_001366142.2; = p.P1255S on NM_020952.6) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.164); catalogued as COSV62592821; called by muse, mutect2, varscan2
- TRRAP | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.042); catalogued as COSV62852084; called by muse, mutect2, varscan2
- TTC7B | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs201941721, COSV60637218; called by muse, mutect2, varscan2
- TTF1 | c.821dup p.S275Vfs*2 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs770528448; called by mutect2, varscan2
- VCL | c.2851C>T p.P951S | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.987); catalogued as rs774356864, COSV53013443; called by muse, mutect2
- VNN1 | c.1247A>G p.E416G | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV63390776; called by muse, mutect2, varscan2
- WWC3 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.11); catalogued as COSV66506267; called by muse, mutect2, varscan2
- XK | c.206T>G p.V69G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV66120715; called by muse, mutect2
- ZNF277 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.159); catalogued as COSV62465806; called by muse, mutect2, varscan2
- ZNF471 | c.256+2T>C p.X86_splice | Splice Site (SNP) | VAF 47/182 reads (26%) | catalogued as COSV57292979; called by muse, mutect2, varscan2
- ADCY1 | c.1682del p.P561Rfs*13 | Frame Shift Del (DEL) | VAF 12/142 reads (8%) | called by mutect2, pindel
- AHNAK2 | c.3493dup p.M1165Nfs*46 | Frame Shift Ins (INS) | VAF 49/173 reads (28%) | called by mutect2, pindel, varscan2
- ARID5B | c.1360_1364dup p.E456Kfs*25 | Frame Shift Ins (INS) | VAF 31/100 reads (31%) | called by mutect2, varscan2
- ATXN2 | c.1410del p.K470Nfs*17 (on ENST00000550104; = p.K310Nfs*17 on NM_002973.4) | Frame Shift Del (DEL) | VAF 81/356 reads (23%) | called by mutect2, pindel, varscan2
- CXorf66 | c.816dup p.H273Tfs*8 | Frame Shift Ins (INS) | VAF 63/241 reads (26%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by muse, mutect2
- IQUB | c.1707del p.H570Ifs*23 | Frame Shift Del (DEL) | VAF 39/124 reads (31%) | called by mutect2, pindel, varscan2
- LCE1C | c.215del p.G72Efs*6 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- PDZD2 | c.2567dup p.D857Gfs*6 | Frame Shift Ins (INS) | VAF 30/127 reads (24%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- PRKDC | c.8110del p.R2704Gfs*13 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- PTEN | c.190del p.H64Ifs*35 | Frame Shift Del (DEL) | VAF 22/148 reads (15%) | called by mutect2, pindel, varscan2
- SLC25A13 | c.1750_1750+25del p.X584_splice | Splice Site (DEL) | VAF 32/158 reads (20%) | called by mutect2, pindel, varscan2
- SLC4A4 | c.317dup p.Q107Sfs*8 (on ENST00000264485 / NM_001098484.3; = p.Q63Sfs*8 on NM_003759.4) | Frame Shift Ins (INS) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.1814del p.K605Sfs*19 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- TDRD5 | c.279dup p.Q94Tfs*6 | Frame Shift Ins (INS) | VAF 32/187 reads (17%) | called by mutect2, pindel, varscan2
- TRBV4-1 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZEB1 | c.2324dup p.E776Gfs*44 | Frame Shift Ins (INS) | VAF 14/101 reads (14%) | called by mutect2, pindel, varscan2
- ZNF705D | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by mutect2, varscan2
- ABCA13 | c.11685T>C p.T3895= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV71292919; called by muse, mutect2
- ABCA9 | c.4623G>A p.Q1541= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV60627103, COSV60629650; called by muse, mutect2
- ABI1 | c.1374A>G p.T458= | Silent (SNP) | VAF 79/161 reads (49%) | catalogued as COSV61019393; called by muse, mutect2, varscan2
- APOB | c.11868A>C p.A3956= | Silent (SNP) | VAF 13/248 reads (5%) | catalogued as COSV51948146; called by muse, mutect2
- ATG7 | c.1879C>A p.R627= | Silent (SNP) | VAF 76/261 reads (29%) | catalogued as COSV61612024, COSV61615022; called by muse, mutect2, varscan2
- AXDND1 | c.990T>C p.I330= | Silent (SNP) | VAF 8/231 reads (3%) | catalogued as COSV62647038; called by muse, mutect2
- C12orf42 | c.771C>T p.H257= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs368267855, COSV59388907; called by muse, mutect2, varscan2
- C2CD5 | c.690C>T p.G230= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs769991906, COSV61723914; called by muse, mutect2, varscan2
- CACNA1I | c.2397C>A p.P799= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV60816055; called by muse, mutect2, varscan2
- CCP110 | c.1587T>C p.S529= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV66817834; called by muse, mutect2
- CMIP | c.423G>A p.L141= (on ENST00000537098 / NM_198390.2; = p.L47= on NM_030629.3) | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs761969732, COSV73345184; called by muse, mutect2, varscan2
- CXorf58 | c.414G>A p.P138= | Silent (SNP) | VAF 47/213 reads (22%) | catalogued as rs371959925, COSV64858720; called by muse, mutect2, varscan2
- DNAJB2 | c.564G>A p.G188= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV60677719; called by muse, mutect2
- DOCK5 | c.1113C>T p.H371= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs756264814, COSV52408995; called by muse, mutect2, varscan2
- DSCAM | c.3459C>T p.D1153= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as rs755076718, COSV68033595; called by muse, mutect2, varscan2
- FLOT2 | c.1047G>A p.Q349= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV67529402; called by muse, mutect2, varscan2
- GBF1 | c.4830G>T p.V1610= (on ENST00000369983 / NM_001377137.1; = p.V1609= on NM_004193.3) | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as COSV64148149; called by muse, mutect2, varscan2
- GREB1 | c.907T>C p.L303= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV52194321; called by muse, mutect2
- GTF3C5 | c.253C>T p.L85= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV59601558; called by muse, mutect2
- HCFC1 | c.1842C>T p.A614= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs782036588, COSV60075989; ClinVar: likely benign; called by muse, mutect2, varscan2
- HERC1 | c.6936A>G p.G2312= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV71249686; called by muse, mutect2
- ICE2 | c.54C>A p.P18= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs748375316, COSV55033034; called by muse, mutect2, varscan2
- IKBKG | c.84C>T p.G28= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs782455868, COSV54839041; called by muse, mutect2, varscan2
- ITGA4 | c.1536C>T p.Y512= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV51997466, COSV52003114; called by muse, mutect2, varscan2
- KCNK18 | c.228G>T p.V76= | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as COSV57972816; called by muse, mutect2
- KHDRBS2 | c.666C>T p.T222= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV55482977; called by muse, mutect2, varscan2
- KIFAP3 | c.756T>C p.P252= | Silent (SNP) | VAF 172/305 reads (56%) | catalogued as rs1471348435, COSV63036365; called by muse, mutect2, varscan2
- KRT8 | c.1329T>C p.F443= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1297517142, COSV53178830; called by muse, mutect2, varscan2
- LIPE | c.1995C>A p.P665= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV54924872; called by muse, mutect2, varscan2
- LRP1B | c.13614G>A p.P4538= | Silent (SNP) | VAF 56/174 reads (32%) | catalogued as rs758111549, COSV67225869; called by muse, mutect2, varscan2
- MAML3 | c.3135A>T p.P1045= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV72209917; called by muse, mutect2, varscan2
- MAP1B | c.3771G>A p.P1257= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs757277389, COSV57095053; called by muse, mutect2, varscan2
- MGAM | c.4416C>T p.D1472= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs751737247, COSV72075382; called by muse, mutect2, varscan2
- MIB2 | c.2067G>A p.A689= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs371136243, COSV100599021; called by muse, mutect2
- MICU1 | c.177T>A p.S59= | Silent (SNP) | VAF 112/493 reads (23%) | catalogued as COSV63147114; called by muse, mutect2, varscan2
- MOBP | c.51G>A p.K17= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1291480453, COSV60655308; called by muse, mutect2, varscan2
- NOM1 | c.960C>T p.S320= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs920437864, COSV51981979; called by muse, mutect2, varscan2
- OBSCN | c.13719C>T p.H4573= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs762207394, COSV52814394; called by muse, mutect2, varscan2
- PAPPA2 | c.1353G>A p.A451= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs766792383, COSV62775861; called by muse, mutect2, varscan2
- PARP12 | c.390T>C p.H130= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV54936479; called by muse, mutect2
- PCDHA11 | c.1572C>T p.H524= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1554164570, COSV56536366; called by muse, mutect2, varscan2
- PLXNA4 | c.1284C>T p.D428= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV58109774, COSV58146810, COSV58153163; called by muse, mutect2, varscan2
- PSD3 | c.1074G>A p.E358= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as COSV58973910, COSV58976834; called by muse, mutect2, varscan2
- PUM2 | c.2118C>T p.G706= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV57584335; called by muse, mutect2, varscan2
- RAB3D | c.78A>C p.L26= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV55792688; called by muse, mutect2, varscan2
- RFPL3 | c.624G>A p.Q208= (on ENST00000249007 / NM_001098535.1; = p.Q179= on NM_006604.2) | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as COSV50752005; called by muse, mutect2
- ROR1 | c.351G>T p.R117= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs755809255, COSV64291847; called by muse, mutect2, varscan2
- SACS | c.447G>A p.A149= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs145681117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGSM1 | c.2280C>T p.N760= (on ENST00000400359 / NM_001039948.4; = p.N699= on NM_133454.3) | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs755280717, COSV63082319; called by muse, mutect2, varscan2
- SIM1 | c.1839A>G p.P613= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV53495480; called by muse, mutect2, varscan2
- SLC6A3 | c.600C>T p.D200= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs1389277721, COSV54368395; called by muse, mutect2
- SLC9A3 | c.2385C>T p.P795= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs765428235, COSV53804482; called by muse, mutect2, varscan2
- TENM1 | c.7608A>G p.T2536= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV64440185; called by muse, mutect2, varscan2
- TGM6 | c.882C>T p.V294= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs762965769, COSV52482870; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2271C>T p.G757= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs201680603; called by muse, mutect2, varscan2
- TTN | c.90471A>G p.P30157= (on ENST00000591111; = p.P22733= on NM_003319.4) | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV60272753; called by muse, mutect2, varscan2
- UXS1 | c.843G>A p.A281= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs779032133, COSV51681424; called by muse, mutect2, varscan2
- VPS41 | c.2115C>T p.D705= | Silent (SNP) | VAF 10/247 reads (4%) | catalogued as COSV59652067; called by muse, mutect2
- XPO6 | c.2568T>C p.P856= | Silent (SNP) | VAF 57/170 reads (34%) | catalogued as COSV58970100; called by muse, mutect2, varscan2
- YOD1 | c.1020A>G p.T340= | Silent (SNP) | VAF 12/248 reads (5%) | catalogued as COSV60006867; called by muse, mutect2
- ZNF569 | c.1467T>C p.S489= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as COSV57598288; called by muse, mutect2, varscan2
- NACA | c.70+4808C>T | Intron (SNP) | VAF 32/74 reads (43%) | catalogued as rs767901186, COSV63272196; called by muse, mutect2, varscan2
- SSPOP | n.9242G>A | RNA (SNP) | VAF 9/41 reads (22%) | catalogued as rs780658784, COSV65135406; called by muse, mutect2, varscan2
- WASF4P | n.978del | RNA (DEL) | VAF 43/148 reads (29%) | called by mutect2, pindel, varscan2
